Surgical pathology report (de-identified scan), TCGA case TCGA-36-2549, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2549-01A (Primary Tumor).

[page 1 of 3]
TCGA - 36 - 2549

Surgical Pathology Consultation Report

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Final Diagnosis:

A. Bilateral tubes and ovaries:

1. Both ovaries replaced by high-grade serous carcinoma (see Comment).
2. The tumour was received fragmented, and therefore the presence or absence of rupture cannot be assessed.
3. No definite serosal involvement by tumour.
4. Microscopic involvement of mucosa of one fallopian tube by tumour.

B. Omentum: Negative for tumour.

C. Uterus with cervix:

1. No evidence of malignancy.
2. Atrophic endometrium.
3. Unremarkable myometrium and cervix.

D. Pelvic washings (): Positive for malignant cells.

[page 2 of 3]
[REDACTED]

Final Diagnosis Comment:

The specimen was received in multiple fragments. As no normal ovary was identified, it is assumed that both ovaries were extensively involved by the tumour. The tumour has a prominent component of cells with abundant clear cytoplasm, a finding allowable in serous carcinomas. The microscopic involvement of the tubal mucosa in one of the fallopian tubes is likely metastatic tumour from the ovarian tumours, but primary in-situ serous carcinoma of the tubal mucosa cannot be completely excluded.

[REDACTED]

Clinical History as Provided by Submitting Physician:

Corresponding Cytology case [REDACTED]

Pelvic mass

Bilateral adnexal masses

Abd/pelvic otherwise (N)

A. Bilateral tubes and ovaries

B. Omentum

C. Uterus and cervix

Specimens Received:

A: bilateral tubes + ovaries

B: omentum

C: uterus + cervix

Gross Description:

The specimen is received in three containers each labelled with the patient's demographics.

Container A is labelled BILATERAL TUBES AND OVARIES and consists of multiple fragments of tumour mass aggregating to 18 x 11 x 5 cm weighing in toto 92 g. Fallopian tubes are identified one measuring 5 cm in length and 0.3 cm in diameter and the second 6 cm in length and 0.4 cm in diameter. Cross-section of the tumour mass shows a fleshy structure with areas of punctate hemorrhage with areas of possible necrosis. No residual ovarian tissue grossly identified. Representative sections are submitted as follows:

A1 -one fallopian tube

A2 -second fallopian tube

[page 3 of 3]
A3-A9 -tumour mass

Container B is labelled OMENTUM and consists of an apron of greater omentum measuring 13 x 10 x 1 cm. Cross-section of the omentum shows unremarkable fat. Representative sections are submitted as B1 through B4.

Container C is labelled UTERUS AND CERVIX and consists of the same weighing 45 g. The uterus measures 6.4 x 3.2 x 2.5 cm. The serosal surface is unremarkable. The cervix measures 3.2 cm in length and 3.1 cm in diameter. The mucosa of the endocervix is normal.

The bivalved uterus shows unremarkable endocervical canal. The endometrium is even with a thickness of 0.1 cm. The myometrium is symmetrical with a maximum thickness of 1.6 cm. Representative sections are submitted as follows:

C1-C2 -cervix, anterior/posterior

C3 -cul-de-sac

C4-C5 -isthmus anterior/posterior

C6-C7 -myometrium anterior/posterior

Source: NCI Genomic Data Commons file fe7b2af7-22af-452b-a4f3-3df18c45fb93 (TCGA-36-2549.42B18428-81F6-48D0-8A5F-FD08926128B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).